Somatic mutation profile of tumor specimen C3N-02030-03 (aliquot CPT0133780091) from CPTAC case C3N-02030, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.7 years (22,893 days).
Specimen C3N-02030-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c4eed5a-ab23-481a-af70-49a90b40ed6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02030-71 (Blood Derived Normal), aliquot CPT0133880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d95239e-07a0-48a0-8b67-ef408eeed880

The open-access MAF lists 690 somatic variants for this specimen: 463 protein-altering or splice-affecting, 143 silent, 84 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 327, Silent 143, Frame Shift Del 73, Intron 48, Frame Shift Ins 24, Nonsense Mutation 20, 3'UTR 11, 5'UTR 10, Splice Site 9, 3'Flank 6, Splice Region 5, 5'Flank 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 108/278 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 62/106 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GRM1 | c.26dup p.A11Sfs*78 | Frame Shift Ins (INS) | VAF 120/312 reads (38%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- PARK7 | c.189del p.E64Rfs*25 | Frame Shift Del (DEL) | VAF 58/300 reads (19%) | catalogued as rs759703272; ClinVar: likely pathogenic; called by mutect2, varscan2
- PRPF6 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs387907100, CM112959, COSV53868700; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.103A>G p.M35V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs876659443, CM110119, COSV64289131, COSV64291926, COSV64310633; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 85/179 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RAD51C | c.837+1G>A p.X279_splice | Splice Site (SNP) | VAF 8/77 reads (10%) | catalogued as rs760235677, CS116093; ClinVar: risk factor / pathogenic; called by muse, mutect2
- TECTA | c.5977C>T p.R1993* | Nonsense Mutation (SNP) | VAF 70/198 reads (35%) | catalogued as rs760574657; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs755655007, COSV99367987; called by muse, varscan2
- ABCA8 | c.4036G>A p.V1346M | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs767871494, COSV52201017; called by muse, mutect2, varscan2
- ABCB9 | c.1672del p.L558Wfs*24 (on ENST00000280560 / NM_019625.4; = p.L515Wfs*24 on NM_019624.3) | Frame Shift Del (DEL) | VAF 66/195 reads (34%) | catalogued as rs1334723787; called by mutect2, pindel, varscan2
- ABCC1 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs756648375; called by muse, mutect2, varscan2
- ACTN4 | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 19/283 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs758778538; called by muse, mutect2
- ADAMTS16 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484616740, COSV56997505; called by muse, mutect2, varscan2
- ADGRL3 | c.2165G>A p.W722* (on ENST00000506720 / NM_001322402.2; = p.W654* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 16/234 reads (7%) | catalogued as COSV72231841; called by muse, mutect2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 141/218 reads (65%) | catalogued as rs748399150; called by mutect2, pindel, varscan2
- AKAP8 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs537526016; called by muse, mutect2, varscan2
- AKAP9 | c.116dup p.R40Efs*7 | Frame Shift Ins (INS) | VAF 18/110 reads (16%) | catalogued as rs765201611; called by mutect2, varscan2
- ALDH7A1 | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 87/229 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as CM121731; called by muse, mutect2, varscan2
- ALG5 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53504362; called by muse, mutect2
- AOX1 | c.1666C>A p.L556I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs769661664; called by muse, mutect2, varscan2
- APOA5 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 197/479 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM120394; called by muse, mutect2, varscan2
- ATP2B3 | c.2132C>T p.T711M | Missense Mutation (SNP) | VAF 105/280 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99051133; called by muse, mutect2, varscan2
- AZU1 | c.483del p.R162Vfs*11 | Frame Shift Del (DEL) | VAF 38/179 reads (21%) | catalogued as rs772652509, COSV99297150; called by mutect2, pindel, varscan2
- B3GAT1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs763308287; called by muse, mutect2, varscan2
- BCL11A | c.2087C>T p.P696L (on ENST00000335712 / NM_001365609.1; = p.P730L on NM_018014.4) | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as rs1432244779; called by muse, mutect2, varscan2
- BMPR1B | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373000965; called by muse, mutect2, varscan2
- BRD2 | c.1932C>A p.Y644* | Nonsense Mutation (SNP) | VAF 55/314 reads (18%) | catalogued as COSV100875888; called by muse, mutect2, varscan2
- CACNB1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs753711036; called by muse, mutect2, varscan2
- CACYBP | c.432del p.V145Sfs*22 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | catalogued as rs1161545619; called by mutect2, pindel, varscan2
- CCDC190 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs373634463; called by muse, mutect2
- CCDC88C | c.3410C>T p.T1137M | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs1173847504, COSV66233428; called by muse, mutect2
- CEBPA | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 173/435 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781549846; called by muse, mutect2, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 7/41 reads (17%) | catalogued as rs768479535; called by mutect2, pindel, varscan2
- CFAP206 | c.1657G>A p.V553I | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs1333669635; called by muse, mutect2, varscan2
- CFAP46 | c.4868C>T p.S1623L | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs1018417455; called by muse, mutect2
- CLDN12 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 57/317 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV55307631; called by muse, mutect2, varscan2
- CLUH | c.377G>A p.R126H (on ENST00000435359; = p.R164H on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1389876216; called by muse, mutect2
- COL14A1 | c.1321+1G>A p.X441_splice | Splice Site (SNP) | VAF 24/47 reads (51%) | catalogued as rs775204866, COSV52852671; called by muse, mutect2, varscan2
- COL27A1 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs781277879, COSV61925278; called by muse, mutect2, varscan2
- COL7A1 | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 156/412 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778104401; called by muse, mutect2, varscan2
- COL8A1 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs558799692; called by muse, mutect2, varscan2
- COQ8A | c.972G>A p.W324* | Nonsense Mutation (SNP) | VAF 39/756 reads (5%) | catalogued as rs1350444582, COSV64656717; called by muse, mutect2
- CPAMD8 | c.1994C>T p.A665V (on ENST00000651564; = p.A618V on NM_015692.5) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV52234755; called by muse, mutect2, varscan2
- CPSF6 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as rs753465837; called by muse, mutect2, varscan2
- CREM | c.364A>G p.R122G (on ENST00000429130; = p.R73G on NM_001881.3) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs188189426; called by muse, mutect2
- CRISPLD2 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 130/300 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as rs372363505; called by muse, mutect2, varscan2
- CSMD1 | c.9422G>A p.R3141H (on ENST00000520002; = p.R3140H on NM_033225.6) | Missense Mutation (SNP) | VAF 83/211 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs768149539, COSV59277588; called by muse, mutect2, varscan2
- D2HGDH | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1472114573, COSV58319342; called by muse, mutect2, varscan2
- DBH | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 174/413 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs199566547; called by muse, mutect2, varscan2
- DCHS1 | c.4222C>T p.R1408C | Missense Mutation (SNP) | VAF 150/338 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs772193454; called by muse, mutect2, varscan2
- DKK4 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs764520274, COSV55183577; called by muse, mutect2, varscan2
- DLEC1 | c.3314C>T p.A1105V | Missense Mutation (SNP) | VAF 128/312 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs780446743, COSV57300501; called by muse, mutect2, varscan2
- DMBT1 | c.7462C>T p.R2488C (on ENST00000338354 / NM_001377530.1; = p.R1731C on NM_004406.3) | Missense Mutation (SNP) | VAF 145/510 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs1437407547; called by muse, mutect2, varscan2
- DOCK5 | c.966del p.F322Lfs*5 | Frame Shift Del (DEL) | VAF 33/95 reads (35%) | catalogued as rs36119599; called by mutect2, pindel, varscan2
- DRC3 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as rs757392054; called by muse, mutect2, varscan2
- DSCAM | c.4862G>A p.R1621Q | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.788); catalogued as rs367647810, COSV101259937; called by muse, mutect2, varscan2
- DTX1 | c.1111G>A p.V371M | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as rs890968014; called by muse, mutect2
- EIF5B | c.608del p.N203Ifs*10 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs1176235101, COSV56813285; called by mutect2, varscan2
- ELOA2 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 22/860 reads (3%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as rs974032541, COSV55308374, COSV55309189; called by muse, mutect2
- EML3 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1465554218; called by muse, mutect2
- EP400 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs200859619; called by muse, mutect2, varscan2
- FAAP100 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.03); catalogued as rs1392568088; called by muse, mutect2
- FAM131B | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 120/317 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs759366087, COSV58367322, COSV58375458; called by muse, mutect2, varscan2
- FAM186A | c.5432C>T p.A1811V | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs765273273; called by mutect2, varscan2
- FEV | c.704dup p.H236Pfs*18 | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | catalogued as rs141171754; called by mutect2, pindel, varscan2
- FKBP8 | c.779C>T p.T260M (on ENST00000222308 / NM_001308373.2; = p.T261M on NM_012181.5) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV55893476; called by muse, mutect2, varscan2
- FLNC | c.4480C>T p.R1494W | Missense Mutation (SNP) | VAF 263/604 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs779079128, COSV100367757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXC2 | c.275_277del p.K92del | In Frame Del (DEL) | VAF 110/768 reads (14%) | catalogued as rs1203250715; called by pindel, varscan2
- FOXD3 | c.1178G>A p.G393D | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.074); catalogued as rs943720041; called by muse, mutect2, varscan2
- FOXE1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64300120; called by muse, mutect2, varscan2
- FRMPD4 | c.3313del p.S1105Vfs*3 | Frame Shift Del (DEL) | VAF 47/255 reads (18%) | catalogued as rs35659462; called by mutect2, pindel, varscan2
- GJD4 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.27); catalogued as COSV58701999; called by muse, mutect2
- GOLGA1 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1394891575; called by muse, varscan2
- GPAT2 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752511500; called by muse, mutect2, varscan2
- GPR137B | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 37/352 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs147078955; called by muse, mutect2, varscan2
- HLF | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1040249035, COSV56831325; called by muse, mutect2
- HNRNPA1 | c.18T>G p.S6= | Splice Region (SNP) | VAF 37/84 reads (44%) | catalogued as rs755898648; called by muse, mutect2, varscan2
- HSPA12A | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 56/232 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs781809567; called by muse, mutect2, varscan2
- INPP4A | c.2930C>T p.T977M (on ENST00000074304 / NM_001134224.1; = p.T938M on NM_004027.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1559132688, COSV50789938; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 32/99 reads (32%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- ITGB6 | c.2330G>A p.R777K | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51791808, COSV51798615; called by muse, mutect2, varscan2
- JAK1 | c.1289dup p.L431Vfs*22 | Frame Shift Ins (INS) | VAF 24/64 reads (38%) | catalogued as rs755650243; called by mutect2, varscan2
- KCNA3 | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1234028653; called by muse, mutect2
- KCNH3 | c.2123del p.G708Efs*11 | Frame Shift Del (DEL) | VAF 63/189 reads (33%) | catalogued as rs1229306184; called by mutect2, pindel, varscan2
- KDM6A | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65040820; called by muse, mutect2, varscan2
- KHDC1 | c.581G>A p.S194N (on ENST00000370384 / NM_001251874.2; = p.S121N on NM_030568.5) | Missense Mutation (SNP) | VAF 101/277 reads (36%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.916); catalogued as rs962762004, COSV57615383; called by muse, mutect2, varscan2
- KIDINS220 | c.4924C>T p.R1642W | Missense Mutation (SNP) | VAF 25/296 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs773095081, COSV56755745; called by muse, mutect2
- KIF26A | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs1462761829; called by muse, mutect2
- KLHL26 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.351); catalogued as rs749078539; called by muse, mutect2, varscan2
- KMT2B | c.7030G>A p.A2344T | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs755245377; called by muse, mutect2, varscan2
- KMT2D | c.10744C>T p.R3582W | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56491153; called by muse, mutect2, varscan2
- KMT2D | c.5927C>T p.S1976L | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV56468464; called by muse, varscan2
- LAGE3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV62074504; called by muse, mutect2, varscan2
- LANCL2 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 56/318 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.487); catalogued as rs770121457, COSV54649883; called by muse, varscan2
- LILRB5 | c.1526G>A p.G509D (on ENST00000449561 / NM_001081442.3; = p.G508D on NM_006840.5) | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV60260780; called by muse, mutect2, varscan2
- LOX | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.07); catalogued as rs1463695782; called by muse, mutect2
- LTB | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs567302751, COSV53000420; called by muse, mutect2
- MAGI2 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV62640251; called by muse, mutect2
- MAGIX | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as COSV66256299; called by muse, mutect2
- MAGIX | c.958dup p.A320Gfs*88 | Frame Shift Ins (INS) | VAF 38/127 reads (30%) | catalogued as rs1321319432; called by mutect2, pindel
- MAML3 | c.2426A>G p.Q809R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as rs1171552463; called by muse, mutect2, varscan2
- MAN2C1 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 88/222 reads (40%) | catalogued as COSV99145269; called by muse, mutect2, varscan2
- MEGF8 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 8/234 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1377476090, COSV52101660, COSV99237367; called by muse, mutect2
- MRC2 | c.1412C>A p.P471H | Missense Mutation (SNP) | VAF 66/330 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57640762; called by muse, mutect2, varscan2
- MTERF3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs750850029; called by muse, mutect2, varscan2
- MYLK | c.4813G>T p.D1605Y | Missense Mutation (SNP) | VAF 172/413 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60610051; called by muse, mutect2, varscan2
- NCOA5 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 40/415 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774397965, COSV51643562; called by muse, mutect2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 20/143 reads (14%) | catalogued as rs759081520; called by mutect2, pindel
- NFX1 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 37/102 reads (36%) | catalogued as rs1451971621; called by muse, mutect2, varscan2
- NOTCH1 | c.3179T>C p.V1060A | Missense Mutation (SNP) | VAF 194/479 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53082811; called by muse, mutect2, varscan2
- NRROS | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751058757, COSV60744792; called by muse, mutect2, varscan2
- NUP188 | c.287A>G p.Y96C | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101001175; called by muse, mutect2
- OBSCN | c.19273G>T p.G6425C | Missense Mutation (SNP) | VAF 28/468 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373919224; called by muse, mutect2
- OBSL1 | c.5045G>A p.R1682H | Missense Mutation (SNP) | VAF 42/414 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as rs1479080818; called by muse, mutect2, varscan2
- ODF3L2 | c.49dup p.L17Pfs*62 | Frame Shift Ins (INS) | VAF 29/88 reads (33%) | catalogued as rs748636054; called by mutect2, pindel, varscan2
- OGA | c.1578del p.M527Cfs*27 | Frame Shift Del (DEL) | VAF 22/243 reads (9%) | catalogued as COSV63382218; called by mutect2, pindel
- OGFOD3 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 91/280 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs756501679, COSV57339492; called by muse, mutect2, varscan2
- OR12D2 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs752585138, COSV65828725; called by muse, mutect2, varscan2
- OR13G1 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1558292655; called by muse, mutect2
- OR2A12 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 135/338 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs749726901, COSV68822033; called by muse, mutect2, varscan2
- OR52D1 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 95/240 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760829167, COSV59487388; called by muse, mutect2, varscan2
- OR5B2 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); catalogued as rs199556711; called by muse, mutect2, varscan2
- OR6C4 | c.616A>G p.M206V | Missense Mutation (SNP) | VAF 93/187 reads (50%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs750194566; called by muse, mutect2, varscan2
- PAX5 | c.76dup p.V26Gfs*49 | Frame Shift Ins (INS) | VAF 50/144 reads (35%) | catalogued as rs767894241; called by mutect2, varscan2
- PAXIP1 | c.300del p.F100Lfs*31 | Frame Shift Del (DEL) | VAF 16/37 reads (43%) | catalogued as rs753190856; called by mutect2, varscan2
- PBRM1 | c.1730A>G p.N577S | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs115997236; called by muse, mutect2, varscan2
- PCDHA5 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 138/340 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.232); catalogued as COSV65352687, COSV65353320, COSV65354029; called by muse, varscan2
- PCLO | c.8192G>A p.R2731H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200140697, COSV61622195; called by muse, mutect2, varscan2
- PCLO | c.7265del p.P2422Lfs*22 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | catalogued as rs1262793592; called by mutect2, pindel, varscan2
- PDE2A | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs138870390, COSV57811844; called by muse, mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as rs759495724; called by mutect2, varscan2
- PGAP6 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 107/346 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs758802749; called by muse, mutect2
- PHACTR4 | c.2032G>T p.E678* (on ENST00000373839 / NM_001350159.2; = p.E688* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV65783415, COSV65785417; called by muse, mutect2, varscan2
- PI4KA | c.5219A>G p.K1740R | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs1390556648, COSV55402756; called by muse, mutect2
- PI4KA | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1460046498, COSV55412316, COSV55422086; called by muse, mutect2, varscan2
- PIAS4 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs765883460; called by muse, mutect2, varscan2
- PIK3C2B | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs373236355; called by muse, mutect2, varscan2
- PKP3 | c.2260_2262del p.K754del | In Frame Del (DEL) | VAF 22/126 reads (17%) | catalogued as rs755089774; called by pindel, varscan2
- PLEKHM1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 85/315 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251964349, COSV69598825; called by muse, mutect2, varscan2
- PMFBP1 | c.929A>G p.H310R | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.528); catalogued as rs1480138422; called by muse, mutect2, varscan2
- POLD1 | c.2789C>T p.A930V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs1060501855; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLK | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.755); catalogued as COSV99605417; called by muse, mutect2, varscan2
- PRDM13 | c.1869C>A p.H623Q | Missense Mutation (SNP) | VAF 212/475 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375460946; called by muse, mutect2, varscan2
- PRDM9 | c.561G>T p.K187N | Missense Mutation (SNP) | VAF 18/303 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV57006227; called by muse, mutect2
- PTH1R | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 175/457 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752454624, COSV57315208; called by muse, mutect2, varscan2
- PWWP2B | c.257del p.P86Lfs*100 | Frame Shift Del (DEL) | VAF 48/166 reads (29%) | catalogued as rs1234606471; called by mutect2, varscan2
- RASSF4 | c.41G>A p.S14N | Missense Mutation (SNP) | VAF 17/276 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.065); catalogued as rs748139811; called by muse, mutect2
- RDH11 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.269); catalogued as rs563954790, COSV101191426; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs751982308; called by mutect2, varscan2
- RNF39 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0.134); catalogued as rs773266930; called by muse, mutect2
- RPL7L1 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100491742; called by muse, mutect2, varscan2
- RXFP1 | c.1823A>G p.Q608R | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs776423555; called by muse, mutect2, varscan2
- SALL2 | c.1586del p.P529Qfs*22 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | catalogued as rs755171367; called by mutect2, pindel, varscan2
- SART3 | c.2063G>A p.C688Y (on ENST00000228284; = p.C670Y on NM_014706.4) | Missense Mutation (SNP) | VAF 24/271 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs755365964, COSV57206827; called by muse, mutect2
- SCNN1D | c.53del p.G18Afs*179 (on ENST00000338555; = p.A151Lfs*18 on NM_001130413.4) | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | catalogued as rs1270083658; called by mutect2, pindel, varscan2
- SIGLEC12 | c.622C>A p.P208T (on ENST00000291707 / NM_053003.4; = p.P90T on NM_033329.2) | Missense Mutation (SNP) | VAF 112/262 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV52463588; called by muse, mutect2, varscan2
- SIPA1 | c.748_750del p.K250del | In Frame Del (DEL) | VAF 39/94 reads (41%) | catalogued as rs1333397145; called by mutect2, pindel, varscan2
- SKIV2L | c.1637del p.G546Afs*83 | Frame Shift Del (DEL) | VAF 7/14 reads (50%) | catalogued as COSV64814087; called by mutect2, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 37/144 reads (26%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC2A11 | c.895G>A p.V299M (on ENST00000345044 / NM_001024938.4; = p.V306M on NM_030807.5) | Missense Mutation (SNP) | VAF 95/241 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs773866178; called by muse, mutect2, varscan2
- SLC43A2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); catalogued as rs746970383; called by muse, mutect2, varscan2
- SLC4A5 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 20/277 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753286986; called by muse, mutect2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | catalogued as rs763364024; called by mutect2, varscan2
- SMC3 | c.127del p.Y43Mfs*69 | Frame Shift Del (DEL) | VAF 21/99 reads (21%) | catalogued as rs1466680694; called by mutect2, pindel, varscan2
- SPATC1L | c.580C>T p.R194C (on ENST00000291672 / NM_001142854.2; = p.R40C on NM_032261.5) | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs751537273; called by muse, mutect2, varscan2
- SPEF2 | c.877dup p.I293Nfs*6 | Frame Shift Ins (INS) | VAF 32/100 reads (32%) | catalogued as rs1390109415; called by mutect2, varscan2
- SPEN | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 151/352 reads (43%) | catalogued as rs1307834195, COSV65365281; called by muse, mutect2, varscan2
- SPEN | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.546); catalogued as rs763959899, COSV65359777; called by muse, mutect2, varscan2
- SPSB4 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776085694, COSV60150454; called by muse, mutect2, varscan2
- SPTA1 | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 65/585 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs752468147; called by muse, mutect2, varscan2
- SPTBN5 | c.5171G>A p.R1724Q | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs199701887; called by muse, mutect2, varscan2
- SRRM1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.53); catalogued as rs1266741422; called by muse, mutect2, varscan2
- SRRM4 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 79/214 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs377333031; called by muse, mutect2, varscan2
- SYNE2 | c.5488del p.S1830Vfs*11 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | catalogued as rs1433291261; called by mutect2, pindel, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 31/84 reads (37%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 37/106 reads (35%) | catalogued as rs748021112; called by mutect2, varscan2
- TDRKH | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767475622, COSV58617972; called by muse, varscan2
- TENT5B | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56693344; called by muse, mutect2, varscan2
- TET2 | c.2511T>A p.N837K | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs755404521; called by muse, mutect2, varscan2
- TFCP2L1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 98/218 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55292626; called by muse, mutect2, varscan2
- TM9SF2 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs767936414; called by muse, mutect2
- TMEM184B | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 51/323 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62672464; called by muse, mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | catalogued as rs770800449; called by mutect2, varscan2
- TNS3 | c.1570G>A p.G524S | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as rs1334788076, COSV100235663, COSV60800954; called by muse, mutect2, varscan2
- TOGARAM2 | c.421T>C p.S141P | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1323135738; called by muse, mutect2, varscan2
- TRAPPC12 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV60845878; called by muse, mutect2
- TRAV3 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 74/223 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs745851436; called by muse, mutect2, varscan2
- TRIM2 | c.1087G>A p.A363T (on ENST00000437508; = p.A390T on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as rs754123914; called by muse, mutect2, varscan2
- TRIM31 | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs928628355; called by muse, mutect2, varscan2
- TRIM9 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 151/333 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV100030317; called by muse, mutect2, varscan2
- TRPV1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs903705338, COSV51518182; called by muse, mutect2, varscan2
- TTLL1 | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1569403339, COSV56740189; called by muse, mutect2
- TUBA3D | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.203); catalogued as rs745718611, COSV58312359; called by muse, mutect2, varscan2
- USP11 | c.2260C>T p.R754C (on ENST00000218348; = p.R711C on NM_001371072.1) | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54475444; called by muse, mutect2
- USP33 | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as rs749382743, COSV62468280; called by muse, mutect2, varscan2
- VANGL2 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 67/288 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.144); catalogued as COSV100925573; called by muse, mutect2, varscan2
- WDFY4 | c.7295G>A p.C2432Y | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs1214976776; called by muse, mutect2
- WDR4 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100374998; called by muse, mutect2, varscan2
- XIRP1 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 73/148 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs775595813, COSV100453679; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 112/365 reads (31%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- ZBED2 | c.27G>T p.E9D | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.023); catalogued as COSV51920425; called by muse, mutect2, varscan2
- ZBED8 | c.894_897del p.N299Sfs*21 | Frame Shift Del (DEL) | VAF 35/77 reads (45%) | catalogued as rs1184980267; called by mutect2, pindel, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | catalogued as rs781677398, COSV57709922; called by mutect2, pindel, varscan2
- ZNF496 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); catalogued as rs758982919, COSV54175637; called by muse, mutect2, varscan2
- ZNF512B | c.2290G>A p.V764M | Missense Mutation (SNP) | VAF 80/185 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs768660385, COSV53871876; called by muse, mutect2, varscan2
- ZNF697 | c.1547del p.T516Rfs*66 | Frame Shift Del (DEL) | VAF 97/251 reads (39%) | catalogued as COSV70284359; called by mutect2, pindel, varscan2
- ACAP3 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 216/515 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACBD3 | c.328T>A p.L110M | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTN4 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 170/431 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM21 | c.902del p.N301Ifs*4 | Frame Shift Del (DEL) | VAF 24/97 reads (25%) | called by mutect2, varscan2
- ADAM30 | c.2102T>C p.L701P | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ADCY3 | c.2186A>G p.Q729R | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- AHRR | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- AKAP9 | c.6111dup p.L2038Tfs*8 (on ENST00000359028; = p.L2006Tfs*8 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- ALG13 | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2
- AOC3 | c.957A>C p.Q319H | Missense Mutation (SNP) | VAF 49/266 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- AP4B1 | c.618-7dup | Splice Region (INS) | VAF 6/66 reads (9%) | called by mutect2, pindel
- APBA2 | c.1918-1G>T p.X640_splice | Splice Site (SNP) | VAF 39/372 reads (10%) | called by muse, mutect2, varscan2
- APBB2 | c.1553A>T p.K518I (on ENST00000295974 / NM_001166050.2; = p.K519I on NM_004307.2) | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- ARAP3 | c.1180del p.R394Dfs*21 | Frame Shift Del (DEL) | VAF 38/217 reads (18%) | called by mutect2, pindel, varscan2
- ARID1A | c.4899del p.M1634* | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | called by mutect2, pindel, varscan2
- ARID5A | c.1772dup p.N591Kfs*33 | Frame Shift Ins (INS) | VAF 68/162 reads (42%) | called by mutect2, pindel, varscan2
- ATP13A3 | c.148A>G p.M50V | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, varscan2
- ATP2B4 | c.49A>C p.S17R | Missense Mutation (SNP) | VAF 54/231 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- BCL11A | c.691del p.L231Cfs*15 (on ENST00000335712 / NM_001365609.1; = p.L265Cfs*15 on NM_018014.4) | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- BSCL2 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 82/418 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- C16orf89 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C1orf68 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 42/584 reads (7%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); called by muse, mutect2
- CA6 | c.501+2T>C p.X167_splice | Splice Site (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2, varscan2
- CBX2 | c.977dup p.H329Afs*84 | Frame Shift Ins (INS) | VAF 36/93 reads (39%) | called by mutect2, pindel, varscan2
- CCDC85C | c.1028G>A p.S343N | Missense Mutation (SNP) | VAF 135/268 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CD6 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 94/264 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CDH17 | c.1504del p.V502Lfs*13 | Frame Shift Del (DEL) | VAF 22/92 reads (24%) | called by mutect2, pindel
- CDK10 | c.85_87+6del p.X29_splice | Splice Site (DEL) | VAF 19/176 reads (11%) | called by mutect2, pindel, varscan2
- CEACAM19 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CELF3 | c.950C>A p.P317H | Missense Mutation (SNP) | VAF 21/448 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CEP78 | c.904A>G p.M302V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHST7 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 57/195 reads (29%) | called by muse, mutect2, varscan2
- CILP2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- CMIP | c.805C>T p.R269* (on ENST00000537098 / NM_198390.2; = p.R175* on NM_030629.3) | Nonsense Mutation (SNP) | VAF 53/153 reads (35%) | called by muse, mutect2, varscan2
- CNOT1 | c.6575T>G p.F2192C | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- COCH | c.1267T>C p.C423R (on ENST00000216361 / NM_001347720.1; = p.C358R on NM_004086.3) | Missense Mutation (SNP) | VAF 97/203 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COX10 | c.1115_1116insA p.V373Cfs*92 | Frame Shift Ins (INS) | VAF 86/258 reads (33%) | called by mutect2, pindel, varscan2
- CRAMP1 | c.1938dup p.A647Rfs*29 | Frame Shift Ins (INS) | VAF 49/157 reads (31%) | called by mutect2, pindel, varscan2
- CRHR2 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- CRY2 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CSMD2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- CSMD3 | c.9577C>T p.Q3193* (on ENST00000297405 / NM_001363185.1; = p.Q3024* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 52/159 reads (33%) | called by muse, mutect2, varscan2
- CYTH2 | c.1134C>A p.D378E (on ENST00000427476; = p.D377E on NM_004228.7) | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- DCAF8L2 | c.1006A>G p.T336A | Missense Mutation (SNP) | VAF 15/228 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2
- DCBLD1 | c.114T>C p.G38= | Splice Region (SNP) | VAF 12/120 reads (10%) | called by muse, mutect2
- DCHS1 | c.2618del p.P873Qfs*5 | Frame Shift Del (DEL) | VAF 103/326 reads (32%) | called by mutect2, pindel, varscan2
- DDR2 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 87/438 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DENND1A | c.1940C>A p.A647D | Missense Mutation (SNP) | VAF 26/377 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- DLL1 | c.1443del p.V482Sfs*55 | Frame Shift Del (DEL) | VAF 18/190 reads (9%) | called by mutect2, pindel
- DMTF1 | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 80/227 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAH1 | c.11242C>T p.H3748Y | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DNAJB11 | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DNHD1 | c.5237C>T p.P1746L | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOCK2 | c.144C>A p.Y48* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- DVL1 | c.722C>T p.T241I | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- E2F8 | c.1433del p.P478Qfs*2 | Frame Shift Del (DEL) | VAF 83/224 reads (37%) | called by mutect2, pindel, varscan2
- ECHDC1 | c.136del p.T46Hfs*24 (on ENST00000531967 / NM_001139510.1; = p.T40Hfs*24 on NM_018479.3) | Frame Shift Del (DEL) | VAF 32/95 reads (34%) | called by mutect2, pindel, varscan2
- EHF | c.712A>G p.R238G | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ELAPOR2 | c.833del p.N278Ifs*47 (on ENST00000450689 / NM_001142749.3; = p.N111Ifs*47 on NM_152748.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel, varscan2
- EP400 | c.3949C>T p.H1317Y | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ERAP1 | c.241A>G p.K81E | Missense Mutation (SNP) | VAF 49/486 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ERF | c.346T>C p.Y116H | Missense Mutation (SNP) | VAF 10/219 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ERICH3 | c.2296del p.T766Rfs*23 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- ESYT1 | c.28A>G p.S10G | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ETFRF1 | c.128del p.N43Tfs*4 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- EXOC4 | c.33A>C p.R11S | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.264); called by muse, mutect2
- FBN2 | c.7240G>T p.G2414C | Missense Mutation (SNP) | VAF 222/478 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- FBXW7 | c.664_667delinsAG p.R223Pfs*32 (on ENST00000281708 / NM_001349798.2; = p.R143Pfs*32 on NM_018315.5) | Frame Shift Del (DEL) | VAF 57/179 reads (32%) | called by pindel, varscan2*
- FCSK | c.2912C>T p.A971V | Missense Mutation (SNP) | VAF 114/283 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- FLT4 | c.2251T>C p.C751R | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- FMNL1 | c.240dup p.A81Rfs*23 | Frame Shift Ins (INS) | VAF 84/273 reads (31%) | called by mutect2, pindel, varscan2
- FNBP4 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- FOXO3 | c.212del p.G71Dfs*49 | Frame Shift Del (DEL) | VAF 45/151 reads (30%) | called by mutect2, pindel, varscan2
- FTO | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 75/215 reads (35%) | called by muse, mutect2, varscan2
- FZD4 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GABRA6 | c.211T>C p.S71P | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRQ | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- GALK1 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GALNT7 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GAREM1 | c.1916G>A p.R639K (on ENST00000269209 / NM_001242409.2; = p.R638K on NM_022751.3) | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2
- GGTLC1 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 51/732 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2
- GLI3 | c.1978T>C p.S660P | Missense Mutation (SNP) | VAF 131/291 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GNE | c.1540G>T p.G514* (on ENST00000396594 / NM_001128227.3; = p.G483* on NM_005476.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/390 reads (3%) | called by muse, mutect2
- GON4L | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 113/462 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GPAM | c.1961G>A p.G654D | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPATCH1 | c.208G>T p.G70* | Nonsense Mutation (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- GPR75 | c.719del p.P240Lfs*2 | Frame Shift Del (DEL) | VAF 61/162 reads (38%) | called by mutect2, pindel, varscan2
- GRIN2B | c.99del p.S34Afs*38 | Frame Shift Del (DEL) | VAF 30/166 reads (18%) | called by mutect2, pindel, varscan2
- GSTA3 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- H2BC12 | c.174G>T p.K58N | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.557); called by muse, mutect2
- HERC1 | c.14137C>T p.P4713S | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HGS | c.1067A>G p.E356G | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HIVEP1 | c.6791A>G p.Q2264R | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HIVEP2 | c.1091_1092del p.T364Sfs*18 | Frame Shift Del (DEL) | VAF 45/153 reads (29%) | called by pindel, varscan2
- HOXA5 | c.282C>A p.H94Q | Missense Mutation (SNP) | VAF 106/239 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- HSPA8 | c.1573T>C p.Y525H | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); called by muse, mutect2
- HSPB1 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 174/450 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- ICAM5 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IGF1R | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IL3RA | c.898_901del p.N300Hfs*9 | Frame Shift Del (DEL) | VAF 91/248 reads (37%) | called by mutect2, pindel, varscan2
- IL6ST | c.5T>C p.L2S | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INPPL1 | c.2337_2339del p.K779_S780delinsN | In Frame Del (DEL) | VAF 30/76 reads (39%) | called by mutect2, pindel, varscan2
- IRS2 | c.3965G>A p.S1322N | Missense Mutation (SNP) | VAF 98/241 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- IRX2 | c.305dup p.Y103Vfs*87 | Frame Shift Ins (INS) | VAF 17/144 reads (12%) | called by mutect2, pindel, varscan2
- ITGA6 | c.276del p.P93Hfs*37 | Frame Shift Del (DEL) | VAF 170/403 reads (42%) | called by mutect2, varscan2
- JAK1 | c.2405_2408del p.K802Rfs*11 | Frame Shift Del (DEL) | VAF 54/152 reads (36%) | called by mutect2, pindel, varscan2
- JAM3 | c.240del p.F80Lfs*21 | Frame Shift Del (DEL) | VAF 77/228 reads (34%) | called by mutect2, pindel, varscan2
- JARID2 | c.1272del p.R425Gfs*36 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
- JPH2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 130/321 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- KDM4B | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, varscan2
- KDM4C | c.2585T>G p.F862C | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.965); called by muse, mutect2
- KEL | c.1969C>A p.H657N | Missense Mutation (SNP) | VAF 26/448 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- KIF1A | c.4946C>T p.T1649I (on ENST00000320389 / NM_001379639.1; = p.T1641I on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.894); called by muse, mutect2
- KIF5B | c.1985A>G p.E662G | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KISS1 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 144/801 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KLHL13 | c.755G>A p.C252Y | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KLHL26 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KLHL29 | c.1008A>C p.E336D | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KMT2B | c.4498-1G>C p.X1500_splice | Splice Site (SNP) | VAF 60/133 reads (45%) | called by muse, mutect2, varscan2
- KMT2D | c.14818C>T p.P4940S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- LAMA1 | c.9121A>G p.R3041G | Missense Mutation (SNP) | VAF 137/315 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LAMA2 | c.7105A>G p.R2369G | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); called by muse, mutect2
- LARP1 | c.911del p.P304Qfs*22 (on ENST00000518297 / NM_033551.3; = p.P227Qfs*22 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 74/250 reads (30%) | called by pindel, varscan2
- LBR | c.1806C>A p.Y602* | Nonsense Mutation (SNP) | VAF 16/310 reads (5%) | called by muse, mutect2
- LDLR | c.2530G>T p.G844C | Missense Mutation (SNP) | VAF 62/338 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMX1A | c.496+1G>A p.X166_splice | Splice Site (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- LMX1A | c.104G>A p.C35Y | Missense Mutation (SNP) | VAF 75/319 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRCH3 | c.997dup p.S333Ffs*12 | Frame Shift Ins (INS) | VAF 22/56 reads (39%) | called by mutect2, pindel, varscan2
- LYST | c.8494A>G p.S2832G | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAN2B1 | c.2178del p.K727Rfs*39 | Frame Shift Del (DEL) | VAF 69/319 reads (22%) | called by mutect2, pindel, varscan2
- MAP1B | c.3196A>G p.T1066A | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARK3 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- MCM5 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MDC1 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 71/266 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- MEGF11 | c.2354dup p.G786Rfs*12 | Frame Shift Ins (INS) | VAF 14/131 reads (11%) | called by mutect2, pindel, varscan2
- MEN1 | c.881T>A p.L294Q | Missense Mutation (SNP) | VAF 178/437 reads (41%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MFN2 | c.2070-7T>C | Splice Region (SNP) | VAF 28/432 reads (6%) | called by muse, mutect2
- MGRN1 | c.1283G>A p.C428Y | Missense Mutation (SNP) | VAF 124/332 reads (37%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- MIPEP | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MKNK2 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 90/224 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MLH3 | c.4013T>C p.L1338P (on ENST00000355774 / NM_001040108.2; = p.L1314P on NM_014381.3) | Missense Mutation (SNP) | VAF 12/390 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- MNDA | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MPHOSPH8 | c.641A>G p.K214R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MPP3 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYF6 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 31/330 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MYOF | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.021); called by muse, mutect2
- NAV3 | c.7153C>A p.L2385I (on ENST00000397909 / NM_001024383.2; = p.L2363I on NM_014903.6) | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NECAB1 | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 121/258 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHS | c.1462del p.R488Gfs*68 | Frame Shift Del (DEL) | VAF 20/156 reads (13%) | called by mutect2, pindel, varscan2
- NOL6 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 53/299 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPR3 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUMA1 | c.25del p.A9Lfs*7 | Frame Shift Del (DEL) | VAF 99/257 reads (39%) | called by mutect2, varscan2
- NUP214 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NUP42 | c.77G>T p.R26M | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- NYAP1 | c.1714del p.V572Cfs*2 | Frame Shift Del (DEL) | VAF 16/115 reads (14%) | called by mutect2, pindel, varscan2
- OR4S2 | c.352T>C p.Y118H | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- ORC1 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- ORC5 | c.1029dup p.H344Tfs*25 | Frame Shift Ins (INS) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- OTOG | c.5639del p.P1880Qfs*99 | Frame Shift Del (DEL) | VAF 122/352 reads (35%) | called by mutect2, pindel, varscan2
- P2RX2 | c.869C>A p.P290H (on ENST00000343948 / NM_170683.4; = p.P218H on NM_012226.5) | Missense Mutation (SNP) | VAF 92/279 reads (33%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- P4HA2 | c.82+2T>A p.X28_splice | Splice Site (SNP) | VAF 75/163 reads (46%) | called by muse, mutect2, varscan2
- PAPOLA | c.958T>G p.Y320D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PAPSS1 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 144/369 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PBX3 | c.467T>C p.L156S | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA3 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHGA3 | c.2224G>T p.G742C | Missense Mutation (SNP) | VAF 191/458 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCK1 | c.1646G>A p.S549N | Missense Mutation (SNP) | VAF 56/307 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDCD1 | c.337G>C p.A113P | Missense Mutation (SNP) | VAF 20/559 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); called by muse, mutect2
- PDPR | c.2341C>A p.L781I | Missense Mutation (SNP) | VAF 97/359 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PIGQ | c.1802C>A p.P601H | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- PIK3AP1 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 66/270 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PITRM1 | c.2922G>T p.M974I | Missense Mutation (SNP) | VAF 84/279 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, varscan2
- PKP2 | c.752G>C p.S251T | Missense Mutation (SNP) | VAF 148/360 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- PNMA8B | c.1421G>A p.G474D | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- POU3F3 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 136/320 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- PPP4R3A | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRCC | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 59/330 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRICKLE2 | c.1027C>T p.H343Y (on ENST00000295902; = p.H287Y on NM_198859.4) | Missense Mutation (SNP) | VAF 12/315 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.303); called by muse, mutect2
- PRIMPOL | c.658del p.S220Qfs*47 | Frame Shift Del (DEL) | VAF 43/191 reads (23%) | called by mutect2, pindel, varscan2
- PRKDC | c.7889C>T p.P2630L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRMT3 | c.1345A>G p.T449A | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- PRR14 | c.836del p.P279Qfs*2 | Frame Shift Del (DEL) | VAF 9/67 reads (13%) | called by mutect2, pindel
- PRRT1 | c.895C>T p.H299Y | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- PTK7 | c.1320dup p.P441Tfs*35 | Frame Shift Ins (INS) | VAF 45/158 reads (28%) | called by mutect2, pindel, varscan2
- PTPN1 | c.1130del p.G377Efs*27 | Frame Shift Del (DEL) | VAF 27/94 reads (29%) | called by mutect2, pindel, varscan2
- PTPN13 | c.1505G>A p.S502N | Missense Mutation (SNP) | VAF 76/222 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTPN21 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 95/254 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTPRQ | c.1045G>T p.G349* (on ENST00000616559; = p.G307* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- RAI14 | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RASAL2 | c.918A>T p.E306D | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RBPJ | c.663del p.F221Lfs*42 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | called by mutect2, pindel
- RFX1 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 89/203 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RHBDF1 | c.776A>G p.D259G | Missense Mutation (SNP) | VAF 15/313 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- RLIM | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPE | c.620G>T p.R207I (on ENST00000359429 / NM_001318926.1; = p.R157I on NM_006916.2) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RPS6KA6 | c.2076T>G p.D692E | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RUBCNL | c.1081T>A p.S361T | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.062); called by muse, mutect2
- SCO2 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 214/542 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SESN3 | c.269T>A p.L90* | Nonsense Mutation (SNP) | VAF 54/210 reads (26%) | called by muse, mutect2, varscan2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 40/60 reads (67%) | called by mutect2, varscan2
- SFXN3 | c.853del p.L285Cfs*14 | Frame Shift Del (DEL) | VAF 30/106 reads (28%) | called by mutect2, pindel, varscan2
- SGK1 | c.601T>G p.F201V | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHISA6 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 273/657 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- SHLD2 | c.1285del p.T429Hfs*3 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | called by mutect2, varscan2
- SLC27A2 | c.1347dup p.L450Tfs*6 | Frame Shift Ins (INS) | VAF 8/76 reads (11%) | called by mutect2, pindel
- SLC8A2 | c.107G>T p.S36I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.276); called by muse, mutect2
- SLC9A2 | c.1787G>A p.S596N | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLMAP | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMARCA4 | c.3697A>G p.M1233V | Missense Mutation (SNP) | VAF 62/550 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SMARCAD1 | c.1217A>G p.Q406R | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SORCS3 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 121/407 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SSC5D | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 72/303 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SST | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 17/380 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- STOX1 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- STUB1 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 32/492 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2
- SUSD2 | c.16C>A p.L6M | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.641); called by muse, mutect2
- SVEP1 | c.9540del p.K3180Nfs*8 | Frame Shift Del (DEL) | VAF 55/152 reads (36%) | called by mutect2, pindel, varscan2
- SYNE1 | c.1903del p.M635Cfs*26 (on ENST00000367255 / NM_182961.4; = p.M642Cfs*26 on NM_033071.3) | Frame Shift Del (DEL) | VAF 117/291 reads (40%) | called by mutect2, pindel, varscan2
- SYNE2 | c.5005dup p.M1669Nfs*8 | Frame Shift Ins (INS) | VAF 25/81 reads (31%) | called by pindel, varscan2
- SYNJ2 | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 225/534 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAP2 | c.223del p.L75* | Frame Shift Del (DEL) | VAF 18/199 reads (9%) | called by mutect2, pindel
- TAS2R38 | c.715C>A p.L239M | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); called by muse, mutect2
- TBC1D10B | c.1882C>A p.L628M | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TCF19 | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TINAG | c.296dup p.S100Vfs*5 | Frame Shift Ins (INS) | VAF 35/109 reads (32%) | called by mutect2, pindel, varscan2
- TLK1 | c.968A>G p.Q323R | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM119 | c.240del p.T81Pfs*7 | Frame Shift Del (DEL) | VAF 80/227 reads (35%) | called by mutect2, pindel, varscan2
- TMEM217 | c.230T>C p.L77P | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.281); called by muse, mutect2
- TMEM62 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- TRAV3 | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- TRIM41 | c.1806C>A p.H602Q | Missense Mutation (SNP) | VAF 111/281 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- TRIM64C | c.68T>C p.I23T | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TRIM72 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRMT2A | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC37 | c.3758del p.N1253Ifs*4 | Frame Shift Del (DEL) | VAF 17/123 reads (14%) | called by mutect2, pindel, varscan2
- TTLL5 | c.1559_1561del p.A520del | In Frame Del (DEL) | VAF 38/95 reads (40%) | called by pindel, varscan2
- TTN | c.99470del p.K33157Sfs*12 (on ENST00000591111; = p.K25733Sfs*12 on NM_003319.4) | Frame Shift Del (DEL) | VAF 36/145 reads (25%) | called by pindel, varscan2
- TTN | c.78124A>G p.K26042E (on ENST00000591111; = p.K18618E on NM_003319.4) | Missense Mutation (SNP) | VAF 53/140 reads (38%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UQCR10 | c.28T>A p.L10M | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- UQCRC2 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- USP16 | c.868G>C p.V290L | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- USP47 | c.1205G>T p.R402M (on ENST00000399455 / NM_001372095.1; = p.R314M on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VILL | c.1360A>G p.S454G | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- VWA5B2 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 15/306 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.272); called by muse, mutect2
- ZBTB1 | c.1571dup p.Q525Afs*4 | Frame Shift Ins (INS) | VAF 26/64 reads (41%) | called by mutect2, varscan2
- ZBTB11 | c.2626C>T p.H876Y | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZFHX3 | c.6996dup p.C2333Mfs*2 | Frame Shift Ins (INS) | VAF 51/133 reads (38%) | called by mutect2, pindel, varscan2
- ZMYM3 | c.2699T>C p.M900T | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2
- ZNF236 | c.3056-2A>G p.X1019_splice | Splice Site (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- ZNF449 | c.830del p.P277Qfs*8 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | called by mutect2, pindel, varscan2
- ZNF470 | c.1805T>C p.F602S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF530 | c.107G>T p.R36M | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF689 | c.1134T>G p.C378W | Missense Mutation (SNP) | VAF 9/276 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF746 | c.503C>A p.P168H | Missense Mutation (SNP) | VAF 18/265 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2
- ZNFX1 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- AHNAK | c.14412G>A p.L4804= | Silent (SNP) | VAF 93/256 reads (36%) | called by muse, mutect2, varscan2
- ANHX | c.636G>A p.A212= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as rs565245948; called by muse, mutect2, varscan2
- ANTKMT | c.687C>G p.G229= | Silent (SNP) | VAF 6/105 reads (6%) | called by muse, mutect2
- APC2 | c.6129C>T p.C2043= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as rs1308241401; called by muse, mutect2, varscan2
- ARHGAP27 | c.279C>T p.Y93= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV51817897; called by muse, mutect2
- ARHGAP4 | c.2106T>C p.P702= | Silent (SNP) | VAF 24/445 reads (5%) | called by muse, mutect2
- ARHGEF17 | c.5055G>A p.E1685= | Silent (SNP) | VAF 48/125 reads (38%) | catalogued as rs1016884567; called by muse, mutect2, varscan2
- ASB4 | c.814C>T p.L272= | Silent (SNP) | VAF 78/180 reads (43%) | called by muse, mutect2, varscan2
- ATP6AP1 | c.114G>A p.A38= | Silent (SNP) | VAF 21/163 reads (13%) | catalogued as rs1253717800; called by muse, varscan2
- B3GNT9 | c.864C>T p.G288= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as rs1462443365; called by muse, mutect2, varscan2
- BRWD3 | c.5058C>T p.G1686= | Silent (SNP) | VAF 39/171 reads (23%) | catalogued as rs781010314; called by muse, mutect2, varscan2
- BTBD11 | c.1509G>A p.P503= (on ENST00000280758 / NM_001018072.2; = p.P40= on NM_001017523.2) | Silent (SNP) | VAF 19/359 reads (5%) | catalogued as rs1158212649; called by muse, mutect2
- C10orf120 | c.549A>G p.L183= | Silent (SNP) | VAF 15/145 reads (10%) | called by muse, mutect2, varscan2
- C1QL2 | c.771C>T p.D257= | Silent (SNP) | VAF 11/344 reads (3%) | called by muse, mutect2
- C8B | c.660G>A p.T220= | Silent (SNP) | VAF 132/415 reads (32%) | catalogued as rs370360066; called by muse, mutect2, varscan2
- CA8 | c.480G>A p.P160= | Silent (SNP) | VAF 40/410 reads (10%) | catalogued as rs537454715; called by muse, mutect2
- CAMK2D | c.477C>G p.G159= | Silent (SNP) | VAF 85/201 reads (42%) | called by muse, mutect2, varscan2
- CARMIL2 | c.1683G>A p.R561= | Silent (SNP) | VAF 116/234 reads (50%) | called by muse, mutect2, varscan2
- CBX8 | c.57G>A p.R19= | Silent (SNP) | VAF 35/199 reads (18%) | catalogued as rs1221350080; called by muse, mutect2, varscan2
- CD1E | c.849G>A p.L283= | Silent (SNP) | VAF 32/141 reads (23%) | called by muse, mutect2, varscan2
- CD81 | c.396G>A p.Q132= | Silent (SNP) | VAF 208/492 reads (42%) | called by muse, mutect2, varscan2
- CDCA5 | c.396C>T p.D132= | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as rs765815329, COSV51870761; called by muse, mutect2, varscan2
- CEBPB | c.603G>A p.A201= | Silent (SNP) | VAF 72/155 reads (46%) | catalogued as rs997116351; called by muse, mutect2, varscan2
- COL16A1 | c.2868C>T p.C956= | Silent (SNP) | VAF 20/220 reads (9%) | catalogued as rs183843629; called by muse, mutect2
- COL23A1 | c.402C>T p.D134= | Silent (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- COL4A6 | c.1248C>T p.G416= | Silent (SNP) | VAF 103/250 reads (41%) | called by muse, mutect2, varscan2
- COL9A2 | c.1350C>T p.P450= | Silent (SNP) | VAF 121/303 reads (40%) | catalogued as COSV65622262; called by muse, mutect2, varscan2
- COX7B | c.69G>A p.R23= | Silent (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2, varscan2
- CUBN | c.8742G>A p.A2914= | Silent (SNP) | VAF 32/594 reads (5%) | catalogued as rs142563433; called by muse, mutect2
- CUEDC1 | c.468C>T p.I156= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs111753270; called by muse, mutect2, varscan2
- CYSLTR1 | c.471A>G p.P157= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs1204079251; called by muse, mutect2, varscan2
- DAXX | c.276G>A p.Q92= | Silent (SNP) | VAF 90/201 reads (45%) | catalogued as COSV56472142; called by muse, mutect2, varscan2
- DDB1 | c.2562G>A p.S854= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs771383564; called by muse, mutect2, varscan2
- DHX16 | c.1398C>A p.A466= | Silent (SNP) | VAF 26/356 reads (7%) | called by muse, mutect2
- DLL4 | c.999T>C p.C333= | Silent (SNP) | VAF 84/182 reads (46%) | catalogued as rs773508830; called by muse, mutect2, varscan2
- DLX4 | c.27C>T p.P9= | Silent (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- DST | c.11112G>A p.V3704= (on ENST00000361203 / NM_001374722.1; = p.V1292= on NM_015548.5) | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs772436994; called by muse, mutect2, varscan2
- DYNC1H1 | c.10518C>T p.D3506= | Silent (SNP) | VAF 72/443 reads (16%) | called by muse, mutect2, varscan2
- EPB41L4B | c.1381C>A p.R461= | Silent (SNP) | VAF 18/229 reads (8%) | called by muse, mutect2
- EPN1 | c.711G>A p.R237= (on ENST00000270460 / NM_001321263.1; = p.R212= on NM_013333.3) | Silent (SNP) | VAF 12/336 reads (4%) | catalogued as COSV50039002; called by muse, mutect2
- FBXW5 | c.1617C>A p.R539= | Silent (SNP) | VAF 17/534 reads (3%) | called by muse, mutect2
- FLNC | c.2457C>T p.F819= | Silent (SNP) | VAF 52/623 reads (8%) | catalogued as rs761900404, COSV57951315; ClinVar: likely benign; called by muse, mutect2
- FOXO4 | c.1173C>A p.S391= | Silent (SNP) | VAF 11/192 reads (6%) | called by muse, mutect2
- FTMT | c.177C>A p.T59= | Silent (SNP) | VAF 49/124 reads (40%) | called by muse, mutect2, varscan2
- GAS2L3 | c.405T>C p.I135= | Silent (SNP) | VAF 28/154 reads (18%) | called by muse, mutect2, varscan2
- GPATCH4 | c.714T>C p.A238= | Silent (SNP) | VAF 88/383 reads (23%) | called by muse, mutect2, varscan2
- GTF2F1 | c.879G>A p.Q293= | Silent (SNP) | VAF 21/216 reads (10%) | catalogued as COSV66725853; called by muse, mutect2, varscan2
- H2BC4 | c.162C>T p.G54= | Silent (SNP) | VAF 13/265 reads (5%) | catalogued as rs1169618682, COSV58414773; called by muse, mutect2
- H4C1 | c.96G>A p.K32= | Silent (SNP) | VAF 72/213 reads (34%) | called by muse, mutect2, varscan2
- HCAR1 | c.657C>A p.T219= | Silent (SNP) | VAF 91/218 reads (42%) | catalogued as rs767155988; called by muse, mutect2, varscan2
- HECTD4 | c.10530G>A p.L3510= | Silent (SNP) | VAF 48/111 reads (43%) | catalogued as rs1202396543; called by muse, mutect2, varscan2
- HIRA | c.1809G>A p.R603= | Silent (SNP) | VAF 18/292 reads (6%) | catalogued as rs762213339; called by muse, mutect2
- HIVEP3 | c.1014C>T p.P338= | Silent (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2
- HOXD9 | c.898C>T p.L300= | Silent (SNP) | VAF 60/156 reads (38%) | called by muse, mutect2, varscan2
- HTR1F | c.153C>T p.T51= | Silent (SNP) | VAF 113/313 reads (36%) | catalogued as COSV60390448; called by muse, mutect2, varscan2
- IFI27L2 | c.150C>T p.N50= | Silent (SNP) | VAF 14/276 reads (5%) | catalogued as rs769849022, COSV53128467; called by muse, mutect2
- IGHE | c.381C>T p.F127= | Silent (SNP) | VAF 104/241 reads (43%) | catalogued as rs868912888; called by muse, mutect2, varscan2
- KBTBD11 | c.1644G>A p.T548= | Silent (SNP) | VAF 66/133 reads (50%) | called by muse, mutect2, varscan2
- KCNMA1 | c.1830C>T p.F610= | Silent (SNP) | VAF 68/243 reads (28%) | catalogued as rs202015764; called by muse, mutect2, varscan2
- KIF7 | c.786G>A p.T262= | Silent (SNP) | VAF 14/370 reads (4%) | catalogued as rs1054963355, COSV67998466; called by muse, mutect2
- KIZ | c.1248T>C p.A416= | Silent (SNP) | VAF 20/127 reads (16%) | called by muse, mutect2, varscan2
- KLHL34 | c.693C>T p.D231= | Silent (SNP) | VAF 64/148 reads (43%) | catalogued as rs981857318, COSV65278721; called by muse, mutect2, varscan2
- KRT39 | c.315G>A p.E105= | Silent (SNP) | VAF 52/262 reads (20%) | catalogued as COSV100842175; called by muse, mutect2, varscan2
- LRWD1 | c.1596C>G p.G532= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as rs1195603578; called by muse, mutect2, varscan2
- LTBP2 | c.2856C>T p.Y952= | Silent (SNP) | VAF 203/562 reads (36%) | called by muse, mutect2, varscan2
- MAP2 | c.1566C>T p.T522= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs1202899945, COSV52286814; called by muse, mutect2, varscan2
- MAP3K21 | c.939C>T p.P313= | Silent (SNP) | VAF 20/308 reads (6%) | catalogued as rs1294798585, COSV100786205, COSV100786301; called by muse, mutect2
- MAST4 | c.4398C>T p.H1466= (on ENST00000403625 / NM_001164664.2; = p.H1277= on NM_015183.3) | Silent (SNP) | VAF 103/232 reads (44%) | called by muse, mutect2, varscan2
- MCF2L | c.3273C>T p.G1091= (on ENST00000375608; = p.G1059= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/222 reads (9%) | catalogued as rs745429431; called by muse, mutect2
- MED13L | c.5847C>T p.C1949= | Silent (SNP) | VAF 15/343 reads (4%) | catalogued as rs1207291009; called by muse, mutect2
- MS4A15 | c.297C>T p.H99= (on ENST00000405633 / NM_001098835.2; = p.H6= on NM_152717.3) | Silent (SNP) | VAF 46/125 reads (37%) | called by muse, mutect2, varscan2
- MUC16 | c.32421T>C p.T10807= | Silent (SNP) | VAF 17/241 reads (7%) | called by muse, mutect2
- NFAT5 | c.1680T>C p.S560= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs1031086836; called by muse, mutect2, varscan2
- NKX2-5 | c.300C>T p.P100= | Silent (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- NPAS3 | c.2076G>A p.P692= (on ENST00000356141 / NM_001164749.2; = p.P660= on NM_022123.3) | Silent (SNP) | VAF 23/153 reads (15%) | catalogued as rs1295093051, COSV60840889; called by muse, mutect2, varscan2
- NR4A2 | c.1119C>T p.V373= | Silent (SNP) | VAF 201/435 reads (46%) | catalogued as COSV59894390; called by muse, mutect2, varscan2
- NRXN2 | c.297C>T p.A99= | Silent (SNP) | VAF 40/272 reads (15%) | called by muse, mutect2, varscan2
- NUP62 | c.1377C>T p.N459= | Silent (SNP) | VAF 14/389 reads (4%) | called by muse, mutect2
- OR2T11 | c.465G>A p.L155= | Silent (SNP) | VAF 15/455 reads (3%) | catalogued as COSV100424895; called by muse, mutect2
- OR2V2 | c.63C>T p.H21= | Silent (SNP) | VAF 60/169 reads (36%) | called by muse, mutect2, varscan2
- OTOF | c.5247C>T p.D1749= (on ENST00000272371 / NM_194248.3; = p.D982= on NM_004802.4) | Silent (SNP) | VAF 140/320 reads (44%) | catalogued as rs1340855486, COSV55505013; called by muse, varscan2
- OXR1 | c.1767T>C p.H589= (on ENST00000442977 / NM_001198532.1; = p.H588= on NM_018002.3) | Silent (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- P2RY14 | c.501T>C p.V167= | Silent (SNP) | VAF 11/116 reads (9%) | called by muse, mutect2, varscan2
- P2RY4 | c.841C>T p.L281= | Silent (SNP) | VAF 18/270 reads (7%) | catalogued as rs1472982109; called by muse, mutect2
- PAK6 | c.141G>A p.L47= | Silent (SNP) | VAF 97/250 reads (39%) | called by muse, mutect2, varscan2
- PAOX | c.1116C>A p.A372= | Silent (SNP) | VAF 44/163 reads (27%) | catalogued as COSV53370990, COSV53372538; called by muse, mutect2, varscan2
- PCDH17 | c.1518C>T p.T506= | Silent (SNP) | VAF 112/282 reads (40%) | called by muse, mutect2, varscan2
- PCDHB10 | c.1665C>T p.N555= | Silent (SNP) | VAF 109/362 reads (30%) | called by muse, mutect2, varscan2
- PHF23 | c.366C>A p.P122= | Silent (SNP) | VAF 115/277 reads (42%) | catalogued as COSV50038138; called by muse, mutect2, varscan2
- PICK1 | c.1161G>A p.E387= | Silent (SNP) | VAF 74/185 reads (40%) | catalogued as rs1266755272; called by mutect2, varscan2
- PIRT | c.186C>T p.G62= | Silent (SNP) | VAF 58/135 reads (43%) | catalogued as rs555559126, COSV74119824; called by muse, mutect2, varscan2
- PKD2 | c.180G>A p.R60= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as rs1263674695; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLEC | c.12642C>T p.N4214= (on ENST00000322810 / NM_201380.4; = p.N4104= on NM_000445.5) | Silent (SNP) | VAF 95/406 reads (23%) | catalogued as rs140538836, COSV59653873; called by muse, mutect2, varscan2
- PLXNA1 | c.2322C>T p.Y774= | Silent (SNP) | VAF 140/297 reads (47%) | catalogued as rs147176760; called by muse, mutect2, varscan2
- POC5 | c.1254A>G p.P418= (on ENST00000428202 / NM_001099271.2; = p.P393= on NM_152408.2) | Silent (SNP) | VAF 37/383 reads (10%) | called by muse, mutect2, varscan2
- POPDC2 | c.789C>T p.R263= | Silent (SNP) | VAF 55/267 reads (21%) | catalogued as rs1283131215; called by muse, mutect2, varscan2
- PPP1R12B | c.960G>A p.E320= | Silent (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- PSEN2 | c.771C>T p.G257= | Silent (SNP) | VAF 66/290 reads (23%) | catalogued as rs7539017, COSV60916600; called by muse, mutect2, varscan2
- PTCH1 | c.3360G>A p.E1120= | Silent (SNP) | VAF 204/419 reads (49%) | catalogued as rs1554690458; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTPN18 | c.1146C>T p.S382= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- RALBP1 | c.900G>A p.V300= | Silent (SNP) | VAF 64/153 reads (42%) | called by muse, mutect2, varscan2
- RALY | c.468G>A p.R156= (on ENST00000246194 / NM_016732.3; = p.R140= on NM_007367.4) | Silent (SNP) | VAF 63/202 reads (31%) | called by muse, mutect2, varscan2
- RBM15 | c.1221G>A p.R407= | Silent (SNP) | VAF 89/210 reads (42%) | catalogued as rs777680641; called by muse, mutect2, varscan2
- RIC8A | c.1071G>A p.L357= (on ENST00000526104 / NM_001286134.1; = p.L363= on NM_021932.5) | Silent (SNP) | VAF 27/258 reads (10%) | called by muse, mutect2, varscan2
- RNF175 | c.208C>T p.L70= | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- RTEL1 | c.2007G>A p.Q669= | Silent (SNP) | VAF 6/131 reads (5%) | called by muse, mutect2
- SAP130 | c.705T>A p.A235= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as rs1177435202, COSV99384438; called by muse, mutect2
- SEC24C | c.2955T>C p.N985= | Silent (SNP) | VAF 11/297 reads (4%) | catalogued as rs1317312801; called by muse, mutect2
- SEMA6A | c.729T>C p.Y243= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs774596346; called by muse, mutect2, varscan2
- SETBP1 | c.819G>A p.T273= | Silent (SNP) | VAF 94/272 reads (35%) | catalogued as rs772700161, COSV56336632; called by muse, mutect2, varscan2
- SETBP1 | c.1431A>G p.S477= | Silent (SNP) | VAF 207/504 reads (41%) | called by muse, varscan2
- SLC12A1 | c.2661T>C p.H887= | Silent (SNP) | VAF 10/135 reads (7%) | catalogued as rs1204413639; called by muse, mutect2
- SLC38A10 | c.879G>A p.R293= | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as rs890805935; called by muse, mutect2
- SLC45A1 | c.588C>A p.T196= | Silent (SNP) | VAF 34/455 reads (7%) | called by muse, mutect2
- SLC4A7 | c.3234G>A p.P1078= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as rs747613260, COSV55403551; called by muse, mutect2, varscan2
- SLC5A9 | c.651G>A p.T217= | Silent (SNP) | VAF 74/220 reads (34%) | catalogued as rs61730938, COSV52581784, COSV99361310; called by muse, mutect2, varscan2
- SNPH | c.754C>T p.L252= | Silent (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- SORBS1 | c.1173A>T p.S391= (on ENST00000361941 / NM_001034954.2; = p.S227= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/78 reads (56%) | called by muse, mutect2, varscan2
- SPEG | c.3678C>T p.H1226= | Silent (SNP) | VAF 63/261 reads (24%) | catalogued as rs1388099213; called by muse, mutect2, varscan2
- SRF | c.888C>A p.S296= | Silent (SNP) | VAF 46/520 reads (9%) | called by muse, mutect2
- SSTR4 | c.378C>T p.D126= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as rs770914493, COSV54796826; called by muse, mutect2, varscan2
- STRA6 | c.417T>C p.T139= | Silent (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2
- TAPBPL | c.685C>T p.L229= | Silent (SNP) | VAF 144/373 reads (39%) | catalogued as rs1161833645; called by muse, mutect2, varscan2
- TECTA | c.285C>T p.F95= | Silent (SNP) | VAF 59/253 reads (23%) | catalogued as rs775584376, COSV50817729; called by muse, mutect2, varscan2
- TEX38 | c.216A>C p.R72= | Silent (SNP) | VAF 83/156 reads (53%) | called by muse, mutect2, varscan2
- TFRC | c.2094A>G p.R698= | Silent (SNP) | VAF 93/221 reads (42%) | called by muse, mutect2, varscan2
- THEMIS2 | c.1866G>A p.R622= | Silent (SNP) | VAF 48/119 reads (40%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.762C>T p.P254= | Silent (SNP) | VAF 62/141 reads (44%) | catalogued as rs774631193; called by muse, mutect2, varscan2
- TRNAU1AP | c.849C>A p.I283= | Silent (SNP) | VAF 30/122 reads (25%) | called by muse, mutect2, varscan2
- TTC28 | c.5487T>C p.N1829= | Silent (SNP) | VAF 11/290 reads (4%) | called by muse, mutect2
- TTN | c.73296A>G p.V24432= (on ENST00000591111; = p.V17008= on NM_003319.4) | Silent (SNP) | VAF 27/141 reads (19%) | catalogued as rs761647014; called by muse, mutect2, varscan2
- UPB1 | c.852C>T p.C284= | Silent (SNP) | VAF 199/439 reads (45%) | catalogued as rs781196303, COSV58116158; called by muse, mutect2, varscan2
- USH2A | c.8826C>T p.D2942= | Silent (SNP) | VAF 67/314 reads (21%) | catalogued as rs775823422; called by muse, mutect2, varscan2
- VEGFD | c.438C>T p.C146= | Silent (SNP) | VAF 23/162 reads (14%) | called by muse, mutect2, varscan2
- VGLL2 | c.666G>A p.P222= | Silent (SNP) | VAF 152/354 reads (43%) | called by muse, mutect2, varscan2
- VWC2 | c.492G>A p.A164= | Silent (SNP) | VAF 18/522 reads (3%) | catalogued as rs1261167091; called by muse, mutect2
- WDR90 | c.2143C>T p.L715= | Silent (SNP) | VAF 154/364 reads (42%) | called by muse, mutect2, varscan2
- ZNF544 | c.1680C>T p.N560= | Silent (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- ZNF644 | c.1824G>A p.L608= | Silent (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- ZNF837 | c.1086G>A p.P362= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as rs777300573; called by muse, mutect2
- ZNF850 | c.723T>C p.I241= | Silent (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- ZNF853 | c.1224G>A p.Q408= | Silent (SNP) | VAF 9/197 reads (5%) | called by muse, mutect2
- ZSWIM5 | c.3456C>A p.P1152= | Silent (SNP) | VAF 17/353 reads (5%) | called by muse, mutect2
- AC107023.1 | chr12:40444462 G>A | 5'Flank (SNP) | VAF 50/142 reads (35%) | called by muse, mutect2, varscan2
- AC109583.1 | c.-542-14097C>T | Intron (SNP) | VAF 68/177 reads (38%) | catalogued as rs1190788629; called by muse, mutect2, varscan2
- AC116366.2 | c.-638+7360G>A | Intron (SNP) | VAF 20/453 reads (4%) | called by muse, mutect2
- ADAM1A | n.1368C>T | RNA (SNP) | VAF 63/175 reads (36%) | called by muse, mutect2, varscan2
- ADAMTS10 | c.1900+47G>A | Intron (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- AL353804.6 | chrX:73827353 ins A | 3'Flank (INS) | VAF 18/166 reads (11%) | called by mutect2, pindel, varscan2
- ANXA8 | c.*181C>T | 3'UTR (SNP) | VAF 153/770 reads (20%) | called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57620943 G>A | 3'Flank (SNP) | VAF 122/317 reads (38%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.4948+11575C>A | Intron (SNP) | VAF 28/137 reads (20%) | called by muse, mutect2, varscan2
- ARL13B | c.130+613del | Intron (DEL) | VAF 30/85 reads (35%) | called by mutect2, pindel, varscan2
- B3GALNT2 | c.113-1407G>A | Intron (SNP) | VAF 9/48 reads (19%) | catalogued as rs1383985581; called by muse, mutect2, varscan2
- CACNB1 | c.1332+23G>A | Intron (SNP) | VAF 37/186 reads (20%) | called by muse, mutect2, varscan2
- CDK5RAP3 | chr17:47971080 C>A | 5'Flank (SNP) | VAF 44/118 reads (37%) | called by muse, mutect2, varscan2
- CFAP52 | c.71-1461G>A | Intron (SNP) | VAF 14/83 reads (17%) | catalogued as rs867168009; called by muse, mutect2, varscan2
- COQ8A | c.*34A>T | 3'UTR (SNP) | VAF 53/427 reads (12%) | called by muse, mutect2, varscan2
- CTDSP1 | c.67+557G>A | Intron (SNP) | VAF 103/252 reads (41%) | catalogued as rs910857141; called by muse, mutect2, varscan2
- CUX2 | c.63+65749C>T | Intron (SNP) | VAF 21/198 reads (11%) | called by muse, mutect2
- DDX11 | c.638+900G>A | Intron (SNP) | VAF 117/363 reads (32%) | catalogued as rs1215835829; called by muse, mutect2, varscan2
- DEGS2 | c.-6C>T | 5'UTR (SNP) | VAF 7/133 reads (5%) | catalogued as rs1294129460; called by muse, mutect2
- DOK6 | c.-36C>T | 5'UTR (SNP) | VAF 84/234 reads (36%) | catalogued as rs1218006178, COSV101235037; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.292-45T>G | Intron (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- EGFL6 | c.*50del | 3'UTR (DEL) | VAF 24/68 reads (35%) | catalogued as rs1446348498; called by mutect2, pindel, varscan2
- EMC10 | c.679-266C>G | Intron (SNP) | VAF 41/108 reads (38%) | catalogued as rs779918120, COSV58541974; called by muse, mutect2, varscan2
- ENAH | c.803-282del | Intron (DEL) | VAF 20/226 reads (9%) | called by mutect2, pindel
- FAM181A | c.100-576C>T | Intron (SNP) | VAF 42/111 reads (38%) | called by muse, mutect2, varscan2
- FAS | c.*589C>T | 3'UTR (SNP) | VAF 26/140 reads (19%) | called by muse, mutect2, varscan2
- GABPB1 | c.1036-3590G>A | Intron (SNP) | VAF 25/85 reads (29%) | called by muse, varscan2
- GLYCTK | c.-47G>C | 5'UTR (SNP) | VAF 23/136 reads (17%) | called by muse, mutect2, varscan2
- GNAS | c.2068+240C>T | Intron (SNP) | VAF 64/189 reads (34%) | catalogued as rs967732544; called by muse, mutect2, varscan2
- GPSM1 | c.1207+108C>T | Intron (SNP) | VAF 24/508 reads (5%) | catalogued as rs782357766; called by muse, mutect2
- HEXD | c.*44del | 3'UTR (DEL) | VAF 81/218 reads (37%) | catalogued as rs751615819; called by mutect2, pindel, varscan2
- HYDIN | c.-136G>A | 5'UTR (SNP) | VAF 12/290 reads (4%) | called by muse, mutect2
- JAKMIP2 | c.2413-2775T>C | Intron (SNP) | VAF 69/164 reads (42%) | called by muse, mutect2, varscan2
- KCNC3 | c.*1385C>T | 3'UTR (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- L3MBTL1 | c.1193-30C>T | Intron (SNP) | VAF 39/212 reads (18%) | catalogued as rs374464014; called by muse, mutect2, varscan2
- LRRC27 | chr10:132331751 ins C | 5'Flank (INS) | VAF 23/144 reads (16%) | called by mutect2, pindel, varscan2
- LRRC8D | c.-141C>T | 5'UTR (SNP) | VAF 62/170 reads (36%) | called by muse, mutect2, varscan2
- MAP9 | c.708+52del | Intron (DEL) | VAF 5/45 reads (11%) | called by mutect2, pindel, varscan2
- MAPRE3 | c.267+106G>A | Intron (SNP) | VAF 10/43 reads (23%) | catalogued as rs767804788; called by muse, mutect2
- MDFIC | c.-7G>A | 5'UTR (SNP) | VAF 94/199 reads (47%) | catalogued as rs930922489; called by muse, mutect2, varscan2
- MS4A6A | c.651+10C>T | Intron (SNP) | VAF 133/271 reads (49%) | called by muse, mutect2, varscan2
- MT1A | chr16:56635810 G>A | 5'Flank (SNP) | VAF 14/354 reads (4%) | called by muse, mutect2
- MT1M | c.94+39C>T | Intron (SNP) | VAF 24/366 reads (7%) | catalogued as rs751934155; called by muse, mutect2
- MUC19 | chr12:40421242 del A | 3'Flank (DEL) | VAF 4/9 reads (44%) | catalogued as rs746639059; called by mutect2, varscan2
- MUCL3 | c.946+868A>G | Intron (SNP) | VAF 48/278 reads (17%) | catalogued as rs1305952989, COSV58516256; called by muse, mutect2, varscan2
- NAPA | c.561+148del | Intron (DEL) | VAF 38/92 reads (41%) | catalogued as rs1349876274; called by mutect2, varscan2
- NEK7 | c.198+3306del | Intron (DEL) | VAF 6/25 reads (24%) | catalogued as rs749732874; called by mutect2, pindel
- NGRN | chr15:90275470 T>G | 3'Flank (SNP) | VAF 12/254 reads (5%) | called by muse, mutect2
- NLRC5 | c.4154+205G>T | Intron (SNP) | VAF 35/123 reads (28%) | catalogued as rs1295311548; called by muse, mutect2, varscan2
- NRIP3 | c.*612G>A | 3'UTR (SNP) | VAF 17/44 reads (39%) | catalogued as rs1339089593, COSV100487129; called by muse, mutect2, varscan2
- OGFOD1 | c.301-20del | Intron (DEL) | VAF 16/46 reads (35%) | catalogued as rs771823733; called by mutect2, varscan2
- OR7A2P | n.362G>A | RNA (SNP) | VAF 18/202 reads (9%) | catalogued as rs528570028; called by muse, mutect2
- PADI1 | c.*96dup | 3'UTR (INS) | VAF 152/430 reads (35%) | called by mutect2, pindel, varscan2
- PCSK4 | c.1391+15C>T | Intron (SNP) | VAF 17/100 reads (17%) | catalogued as rs539574874; called by muse, mutect2, varscan2
- PDCD6IP | c.210-984G>A | Intron (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2, varscan2
- PGRMC2 | chr4:128287823 ins C | 5'Flank (INS) | VAF 11/117 reads (9%) | called by mutect2, pindel
- PHYKPL | c.59+17C>T | Intron (SNP) | VAF 44/123 reads (36%) | catalogued as rs749198645; called by muse, mutect2, varscan2
- PI4KAP2 | n.2831C>A | RNA (SNP) | VAF 74/194 reads (38%) | called by muse, varscan2
- PITRM1 | c.2646-904C>T | Intron (SNP) | VAF 14/133 reads (11%) | catalogued as rs919528512; called by muse, mutect2, varscan2
- PLEKHD1 | c.243+99C>T | Intron (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- POLM | c.714+75C>A | Intron (SNP) | VAF 43/97 reads (44%) | called by muse, mutect2, varscan2
- PRKCB | c.-5G>A | 5'UTR (SNP) | VAF 98/220 reads (45%) | called by muse, mutect2, varscan2
- PRRC2C | c.8199+1071G>A | Intron (SNP) | VAF 45/373 reads (12%) | called by muse, mutect2, varscan2
- PUS10 | c.126+907C>T | Intron (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- RAB26 | c.307-380T>G | Intron (SNP) | VAF 58/139 reads (42%) | called by muse, mutect2, varscan2
- RNF14 | chr5:141991892 G>A | 3'Flank (SNP) | VAF 53/143 reads (37%) | called by muse, mutect2, varscan2
- RNF220 | c.1630-10C>G | Intron (SNP) | VAF 36/255 reads (14%) | called by muse, mutect2, varscan2
- RPL28 | c.205+160_205+162del | Intron (DEL) | VAF 32/103 reads (31%) | catalogued as rs750063282; called by mutect2, pindel, varscan2
- SCN4B | c.*317G>A | 3'UTR (SNP) | VAF 191/461 reads (41%) | catalogued as rs1431822176; called by muse, mutect2, varscan2
- SLAMF8 | chr1:159837959 C>T | 3'Flank (SNP) | VAF 60/343 reads (17%) | called by muse, mutect2, varscan2
- SNAP47 | c.1249-4721G>A | Intron (SNP) | VAF 57/279 reads (20%) | catalogued as rs566590122; called by muse, mutect2, varscan2
- SNW1 | c.1413-30T>A | Intron (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- SRD5A3 | c.-33dup | 5'UTR (INS) | VAF 34/117 reads (29%) | called by mutect2, pindel, varscan2
- STAB1 | c.4364-40del | Intron (DEL) | VAF 31/80 reads (39%) | called by mutect2, pindel, varscan2
- STK19 | c.567+22G>A | Intron (SNP) | VAF 23/326 reads (7%) | catalogued as rs1183671537; called by muse, mutect2
- TIMP3 | c.-57C>T | 5'UTR (SNP) | VAF 33/261 reads (13%) | called by muse, varscan2
- TPRXL | n.752C>T | RNA (SNP) | VAF 27/200 reads (14%) | catalogued as rs192562800; called by muse, varscan2
- TTC7B | c.*16C>T | 3'UTR (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- UBR2 | c.1281+157G>A | Intron (SNP) | VAF 35/81 reads (43%) | catalogued as rs978399522; called by muse, mutect2, varscan2
- ZFHX4 | c.3093+97del | Intron (DEL) | VAF 14/96 reads (15%) | catalogued as rs751858242; called by mutect2, varscan2
- ZNF252P | n.245+3153del | Intron (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- ZNF420 | c.*1105A>G | 3'UTR (SNP) | VAF 8/120 reads (7%) | catalogued as rs888810436; called by muse, mutect2
- ZNF582 | c.-150C>T | 5'UTR (SNP) | VAF 8/166 reads (5%) | catalogued as rs1490829928; called by muse, mutect2
- ZRANB3 | c.1206+399del | Intron (DEL) | VAF 19/74 reads (26%) | called by mutect2, pindel, varscan2
